Somatic mutation profile of tumor specimen TCGA-ZG-A9LU-01A (aliquot TCGA-ZG-A9LU-01A-11D-A41K-08) from TCGA case TCGA-ZG-A9LU, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.7 years (24,742 days).
Specimen TCGA-ZG-A9LU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84dfa2fa-aaef-46c7-81e8-1df3e5b9015d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9LU-10A (Blood Derived Normal), aliquot TCGA-ZG-A9LU-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e17b1b26-4d9f-402e-ada8-3b7734e0e3f6

The open-access MAF lists 15 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Frame Shift Ins 1, Silent 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCDC1 | c.5154G>T p.Q1718H (on ENST00000597505 / NM_001367979.1; = p.Q825H on NM_020869.3) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100360857; called by muse, mutect2
- OR8B8 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.633); catalogued as COSV100045340; called by muse, mutect2
- PPP4C | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV54222859; called by muse, mutect2
- RALGAPB | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99486020; called by muse, mutect2, varscan2
- RBM34 | c.1111C>A p.Q371K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100784102; called by muse, mutect2, varscan2
- SIRPB2 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs200805923, COSV63123070; called by muse, mutect2, varscan2
- SLC6A6 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs1375781532, COSV62647583; called by muse, mutect2, varscan2
- STYXL2 | c.535T>C p.Y179H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99610078; called by muse, mutect2, varscan2
- USP24 | c.4740T>G p.C1580W | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV99601312; called by muse, mutect2
- USP9X | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV61075025; called by muse, mutect2, varscan2
- VSTM2A | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs376525790; called by muse, varscan2
- ATP12A | c.1920A>C p.K640N | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NHS | c.4421_4427del p.N1474Rfs*44 | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | called by mutect2, pindel, varscan2
- USP34 | c.1132_1135dup p.F379Yfs*9 | Frame Shift Ins (INS) | VAF 6/66 reads (9%) | called by mutect2, pindel
- CCP110 | c.954T>G p.A318= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as COSV101195366; called by muse, mutect2
